Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A8AZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A8AZ-01A (Primary Tumor).

[page 1 of 2]
Sex: Male Age: DOB:
Physician:
Location:

SURGICAL PATHOLOGY REPORT

Order Number:
Date Completed:

Date Received:
Date Collected:

Diagnosis:

A. Spleen, resection. No histologic abnormality.

B. Splenic flexure, resection. Colon with no histologic abnormality. Three lymph nodes, negative for neoplasm (0/3).

C. Left adrenal gland, left kidney, and distal pancreas, resection. Malignant pheochromocytoma (20.0 cm) involving the adrenal gland and extending into periaxonal soft tissue, pancreas, and kidney, with foci of lymphovascular invasion. Surgical margins negative. One lymph node, negative for neoplasm (0/1).

D. Soft tissue, retroperitoneum, excision: Benign adipose tissue. Negative for neoplasm.

*ICD-O-3
Pheochromocytoma, malignant 8720/3
Site ① Adrenal gland C94.9
JW 11/12/13*

Signing Pathologist:

History:

Source of Specimen: Spleen. Left adrenal mass. Clinical Diagnosis: Pheochromocytoma. Operative Procedure: Open left adrenalectomy, possible splenectomy, possible nephrectomy, possible nephrectomy.

Gross Description:

A. "Spleen" Received in formalin is a 120 gram, 10.0 x 8.5 x 3.0 cm spleen with attached hilar adipose tissue 10.5 x 8.5 x 1.5 cm. The splenic capsule is pink-gray, smooth and glistening and is focally stripped away on the hilar aspect. The spleen is breadloafed to reveal dark red, focally hemorrhagic but otherwise grossly unremarkable cut surfaces. The attached hilar adipose tissue is dissected and palpated, however no lymph nodes are identified.
A1 Representative sections of focally hemorrhagic spleen

B. "Splenic flexure"
Received in a large container filled with formalin is a 12.9 cm (length) x 7.8 cm (internal circumference) segment of transverse colon with attached mesentery and omentum. The colon is grossly unremarkable. Both the mesentery and omentum are grossly unremarkable with no evidence of tumor involvement.
B1 Mesentery
B2 Colon

C. "Left kidney, left adrenal, and distal pancreas" Received in formalin is a 1.72 kg, 20.0 x 15.0 x 11.5 cm resection that includes kidney (12.4 x 6.0 x 4.5 cm), distal pancreas (9.5 x 4.5 x 1.8 cm), and left adrenal gland.

There is an 18.7 x 11.7 x 10.5 cm heterogeneous mass with large areas of predominantly central necrosis, a viable pink, fleshy, nodular tumor predominantly in the periphery with focal areas of hemorrhage, that invades directly into

MRN:

Last Name:

Physician Name

Report Date/Time:

Admit Date:

[page 2 of 2]
Last Name:

First Name:

MRN:

Sex: Male

Age:

DOB:

Physician:

Location:

the kidney diffusely, as well as the pancreas. There 15 cm length of compressed vessel that may represent the renal vein to which the tumor is adherent. Tumor extends into surrounding soft tissue, abutting the soft tissue margin. Possible adrenal gland is present at the superior aspect of the mass. Multiple lymph node candidates appear to have direct invasion by the mass. Soft tissue margin inked blue. Other discrete lesions are not seen within the kidney or pancreas.

Cassette Summary:

- C1. Ureteral margin and possible renal vein margin. Shaved.
- C2. Possible splenic vessel margin.
- C3. Tumor to kidney.
- C4. Tumor adherent to possible renal vein.
- C5. Tumor adherent to pancreas.
- C6. Tumor to possible adrenal gland.
- C7. Possible direct extension of mass into a lymph node, bisected.
- C8. Possible direct extension of mass into lymph node. One representative section.
- C9. One candidate lymph node, bisected.
- C10. One candidate lymph node, sectioned.
- C11. Tumor abutting soft tissue margin.
- C12-C16. Additional representative sections of mass.

D. "Retroperitoneal fat" Received in formalin in a small, tall container is an 8.2 x 3.7 x 1.5 cm adipose tissue that is grossly unremarkable. No lymph nodes identified. Representative sections submitted in two cassettes.

Electronically Signed By:

I, the above named pathologist, have personally examined and interpreted the slides from this case:

House Officer(s):

CPT Codes:

Specimen	CPT Code	Number of Charges
D	88304	0
A, D	88305	2
B, C	88307	1
B, C	88309	1

Staging Discrepancy		
Quality/Quantity/Quantity/Quality		

MRN:

Physician Name:

Last Name:

Report Date/Time:

Admit Date:

Source: NCI Genomic Data Commons file 51f83140-a8b7-4d76-b011-e26858730db0 (TCGA-RW-A8AZ.4C6C5A06-F167-4377-925A-18BA6767B701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).